Somatic mutation profile of tumor specimen 0DKO7I from CCDI case PBBYMI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sertoli-Leydig cell tumor, poorly differentiated; Tissue or organ of origin: Ovary; Age at diagnosis: 15.0 years (5,497 days).
Specimen 0DKO7I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5862e81-eea7-494e-a1bf-380397c080c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKO76 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a17161d-6847-4c07-9da1-6f4673a19e48

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5438A>G p.E1813G | Missense Mutation (SNP) | VAF 418/1035 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58615258, COSV58615306, COSV58615741; called by muse, mutect2, varscan2
- HSPBP1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 45/811 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.46); catalogued as rs866076608; called by muse, mutect2
- OR2M4 | c.668G>C p.R223P | Missense Mutation (SNP) | VAF 237/719 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.482); catalogued as COSV100141064, COSV60707625; called by muse, mutect2, varscan2
- OR5K4 | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 396/1144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100721363, COSV61584060; called by muse, mutect2, varscan2
- SLC7A2 | c.158A>C p.Y53S (on ENST00000494857 / NM_001370338.1; = p.Y93S on NM_003046.6) | Missense Mutation (SNP) | VAF 56/1298 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753135168; called by muse, mutect2
- TNS1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 24/597 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1354496737, COSV50690052; called by muse, mutect2
- ALDH1A2 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 93/1916 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALG13 | c.634T>A p.C212S | Missense Mutation (SNP) | VAF 519/1246 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IFNA1 | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 154/424 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- R3HCC1L | c.1168A>T p.T390S | Missense Mutation (SNP) | VAF 269/754 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TENM3 | c.1862A>G p.N621S | Missense Mutation (SNP) | VAF 330/916 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TFAP2B | c.21C>G p.D7E | Missense Mutation (SNP) | VAF 272/803 reads (34%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MCF2L | c.3043+1341G>A | Intron (SNP) | VAF 68/362 reads (19%) | catalogued as rs569987856; called by muse, mutect2, varscan2
- RNF224 | c.-74C>G | 5'UTR (SNP) | VAF 78/229 reads (34%) | called by muse, mutect2, varscan2
